CCDI case PBCJZX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/13b6d4a2-43b2-4daa-8e13-6ee3a9a366b7

Demographics
Sex at birth: male.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.4 years (6,370 days).

Biospecimens (3 samples)
- Sample 0DTNVJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTNWD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DTNXB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
